Somatic mutation profile of tumor specimen TCGA-G3-A5SJ-01A (aliquot TCGA-G3-A5SJ-01A-11D-A27I-10) from TCGA case TCGA-G3-A5SJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.8 years (21,848 days).
Specimen TCGA-G3-A5SJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edd21a41-e080-42cf-9f4a-91f3ef9e5fda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A5SJ-10A (Blood Derived Normal), aliquot TCGA-G3-A5SJ-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d8cac45-2eae-4fb4-84b0-954c055cbc51

The open-access MAF lists 105 somatic variants for this specimen: 86 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 18, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT2 | c.442T>A p.C148S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65455161; called by muse, mutect2, varscan2
- ADGRL4 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV66066839; called by muse, mutect2, varscan2
- AKAP9 | c.6275A>G p.K2092R (on ENST00000359028; = p.K2060R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62359417; called by muse, mutect2, varscan2
- ALB | c.1459T>G p.L487V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV55743397; called by muse, mutect2, varscan2
- APPBP2 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.14); catalogued as rs768353735, COSV50030401; called by muse, mutect2, varscan2
- ATP5F1A | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as COSV56362146; called by muse, mutect2, varscan2
- BLNK | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56415649; called by muse, mutect2, varscan2
- C1QTNF1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs148895244; called by muse, mutect2, varscan2
- CACNA1E | c.2293C>A p.H765N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62434934; called by muse, varscan2
- CCDC138 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV51709842; called by muse, mutect2, varscan2
- CD163 | c.1937G>T p.W646L | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV63138512; called by muse, mutect2, varscan2
- CHRM3 | c.1593G>C p.W531C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108107, COSV99697992; called by muse, mutect2, varscan2
- CLIP4 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs770539151, COSV60753479; called by muse, mutect2, varscan2
- CPE | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as COSV68582980; called by muse, mutect2, varscan2
- CREBRF | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as COSV51637034; called by muse, mutect2, varscan2
- CTNNB1 | c.998A>T p.Y333F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62693301; called by muse, mutect2
- DAB2IP | c.2479T>G p.S827A (on ENST00000408936; = p.S799A on NM_032552.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52269704; called by muse, varscan2
- DCC | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59142175; called by muse, mutect2, varscan2
- DDAH2 | c.659G>C p.C220S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774241250, COSV65384535; called by muse, mutect2, varscan2
- DLG5 | c.3778C>G p.R1260G | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV64950322; called by muse, mutect2, varscan2
- DPP10 | c.764T>C p.M255T | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758693945, COSV59738423; called by muse, mutect2, varscan2
- ELMO1 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60328757; called by muse, mutect2, varscan2
- EPHB1 | c.2325T>G p.D775E | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.79); catalogued as COSV67673392; called by muse, mutect2, varscan2
- GARS1 | c.2214G>T p.E738D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV66829491; called by muse, mutect2, varscan2
- GCC1 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV58463958; called by muse, mutect2, varscan2
- GPRIN1 | c.2773T>C p.Y925H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754414133, COSV56146391; called by muse, mutect2, varscan2
- GRIPAP1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64553601; called by muse, mutect2, varscan2
- H3C4 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.245); catalogued as COSV61912501; called by muse, mutect2, varscan2
- HOXB5 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53314474; called by muse, mutect2, varscan2
- IQCN | c.3522C>A p.H1174Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.444); catalogued as COSV62748848; called by muse, mutect2, varscan2
- IQGAP2 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1264875033, COSV57184526; called by muse, mutect2, varscan2
- ITPRID1 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748239692, COSV60078216; called by muse, mutect2, varscan2
- KMT2A | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV63293521; called by muse, mutect2, varscan2
- KRT39 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs773957853, COSV62917385; called by muse, mutect2, varscan2
- LRIG2 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1317010200, COSV63164566; called by muse, mutect2, varscan2
- LRP1B | c.11098G>T p.G3700* | Nonsense Mutation (SNP) | VAF 42/140 reads (30%) | catalogued as COSV67261760, COSV67282564; called by muse, varscan2
- LYST | c.3713-2A>T p.X1238_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV67715358; called by muse, mutect2, varscan2
- MAEL | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as rs1335168881, COSV63306620; called by muse, mutect2, varscan2
- MAVS | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV63927755; called by muse, mutect2, varscan2
- MTOR | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 142/206 reads (69%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs753584596, COSV63879326; called by muse, varscan2
- MYEF2 | c.481A>C p.M161L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.841); catalogued as COSV51054861; called by muse, mutect2, varscan2
- MYH7 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV62524926; called by muse, mutect2, varscan2
- NAT8 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766541577, COSV55543068, COSV55543304; called by muse, mutect2, varscan2
- NDRG1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60486320; called by muse, mutect2, varscan2
- NSD1 | c.291T>G p.F97L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV61786221; called by muse, mutect2, varscan2
- ODF2 | c.1039G>A p.G347R (on ENST00000434106 / NM_153433.2; = p.G323R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV63549308; called by muse, varscan2
- PAQR9 | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as COSV61419227; called by muse, mutect2, varscan2
- PCDH7 | c.2982G>T p.R994S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370196952; called by muse, mutect2, varscan2
- PGM3 | c.1297A>C p.K433Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV52286294; called by muse, mutect2, varscan2
- PHF6 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs756384013, COSV59707265; called by muse, mutect2, varscan2
- PLXNA4 | c.1982+1G>A p.X661_splice | Splice Site (SNP) | VAF 32/74 reads (43%) | catalogued as COSV58109532; called by muse, mutect2, varscan2
- PRDM1 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64847310; called by muse, mutect2, varscan2
- PTK2 | c.405C>G p.N135K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV61794037; called by muse, mutect2, varscan2
- PTPN13 | c.1900A>G p.K634E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57419063; called by muse, mutect2, varscan2
- PTPRD | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV61987428; called by muse, mutect2, varscan2
- RBM39 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV53614445; called by muse, mutect2, varscan2
- RPL23A | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.308); catalogued as rs772937257, COSV52645398; called by muse, mutect2, varscan2
- RPTOR | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60810894, COSV60819929; called by muse, mutect2, varscan2
- SCNN1A | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as rs768767909, COSV57437700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK3 | c.4982G>T p.W1661L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53192166; called by muse, mutect2, varscan2
- SLC24A2 | c.1907T>A p.M636K | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53877908; called by muse, mutect2, varscan2
- SREBF2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs751254073, COSV63332970; called by muse, mutect2, varscan2
- SUMF2 | c.333G>C p.W111C (on ENST00000652303; = p.W92C on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV51919375; called by muse, mutect2, varscan2
- SUPV3L1 | c.921A>T p.R307S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62846563; called by muse, mutect2, varscan2
- SYAP1 | c.464C>A p.P155Q | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66467882, COSV66469084; called by muse, mutect2, varscan2
- TC2N | c.630A>C p.R210S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV61748503; called by muse, varscan2
- TEX2 | c.3020A>T p.E1007V (on ENST00000583097 / NM_001288733.2; = p.E1014V on NM_018469.5) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51986144; called by muse, mutect2, varscan2
- TP53 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1567554121, COSV52666570, COSV52937236, COSV53050140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTI1 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV65064081; called by muse, mutect2, varscan2
- UBR4 | c.5911G>A p.G1971R | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64401885; called by muse, mutect2, varscan2
- UNC45B | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV52101561; called by muse, mutect2, varscan2
- USP40 | c.1523C>A p.A508E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV52489531; called by muse, mutect2, varscan2
- XDH | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV65151504; called by muse, mutect2
- ZNF420 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs760437783, COSV58496794; called by muse, mutect2, varscan2
- ZNF451 | c.1100G>T p.C367F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62600509; called by muse, mutect2, varscan2
- ZNF790 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as rs750365504, COSV100764794; called by muse, mutect2, varscan2
- ZPLD1 | c.340C>T p.P114S (on ENST00000466937 / NM_001329788.1; = p.P130S on NM_175056.2) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as COSV60356054; called by muse, mutect2, varscan2
- ANKRD17 | c.2063del p.A688Efs*7 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by pindel, varscan2
- ARHGEF10L | c.984_1007del p.G329_K336del | In Frame Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- CCT6B | c.356_385del p.I119_I128del | In Frame Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel
- CR1L | c.1221_1228+2del | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by pindel, varscan2
- HS2ST1 | c.609_612delinsGAC p.E204Tfs*41 | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by pindel, varscan2*
- KLHDC4 | c.1526_1527del p.D509Gfs*35 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS39 | c.742del p.V248Wfs*86 (on ENST00000348544 / NM_001301138.2; = p.V237Wfs*86 on NM_015289.5) | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- ZNF488 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA4 | c.204G>A p.P68= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs201725352, COSV64671852; called by muse, mutect2, varscan2
- DNAH9 | c.3273C>G p.P1091= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs754016748, COSV52380933; called by muse, mutect2, varscan2
- EMX1 | c.732G>A p.R244= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1403470941, COSV50689208; called by muse, mutect2, varscan2
- GPRIN3 | c.135T>C p.N45= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs372513468; called by muse, mutect2, varscan2
- KCNA5 | c.495C>T p.F165= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs1251090692, COSV52905159; called by muse, mutect2, varscan2
- KRT23 | c.711G>C p.L237= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52929371; called by muse, mutect2, varscan2
- KRT39 | c.900C>A p.T300= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV62918171; called by mutect2, varscan2
- MGAM | c.4266T>C p.N1422= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs369807337; called by muse, mutect2, varscan2
- NAA16 | c.852T>C p.S284= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV65067208; called by muse, mutect2, varscan2
- NDN | c.420C>A p.L140= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV59359712, COSV59361747; called by muse, mutect2, varscan2
- OR2M3 | c.822G>T p.V274= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as COSV71759355; called by muse, mutect2, varscan2
- PHRF1 | c.336C>A p.L112= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV52763999; called by muse, mutect2, varscan2
- PIKFYVE | c.2736C>T p.P912= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV52250261; called by muse, mutect2, varscan2
- SLC7A9 | c.1233A>T p.V411= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as COSV50096273; called by muse, mutect2, varscan2
- SLC8A3 | c.900C>T p.N300= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV63524784, COSV63527524; called by muse, mutect2, varscan2
- SOX9 | c.627C>T p.A209= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as rs752697003, COSV55429651; called by muse, mutect2, varscan2
- ZNF711 | c.1842T>C p.T614= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as COSV52159763; called by muse, mutect2, varscan2
- ZNF790 | c.1218C>T p.S406= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100764792; called by muse, mutect2, varscan2
- BEND2 | c.-2C>T | 5'UTR (SNP) | VAF 28/42 reads (67%) | catalogued as rs1323717738, COSV101191907; called by muse, mutect2, varscan2
